Surgical pathology report (de-identified scan), TCGA case TCGA-50-5045, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5045-01A (Primary Tumor).

FINAL DIAGNOSIS:**Summary Statement**

The right lower lobe neoplasm is an invasive poorly differentiated adenocarcinoma (2.5 cm) with pleural and angiolymphatic invasion. Two sump nodes (Parts 4 and 7) are involved by metastatic adenocarcinoma. All margins of resection are free of tumor. The stage is T2 N1 MX.

PART 1: BONE, SIXTH (6TH) RIB, RESECTION –
PENDING DECALCIFICATION.

PART 2: BONE, FIFTH (5TH) RIB, RESECTION –
PENDING DECALCIFICATION.

PART 3: LYMPH NODE, NEAR RIGHT STEM BRONCHUS, BIOPSY –
TWO (2) BENIGN REACTIVE LYMPH NODES. NO TUMOR SEEN.

PART 4: LYMPH NODE, 11R SUMP NODE, BIOPSY –
ONE OF ONE (1/1) LYMPH NODE WITH METASTATIC ADENOCARCINOMA.

PART 5: LYMPH NODE, 11 BASILAR VEIN, BIOPSY –
ONE (1) BENIGN REACTIVE LYMPH NODE. NO TUMOR SEEN.

PART 6: LUNG, BASILAR SEGMENT OF RIGHT LOWER LOBE, SEGMENTECTOMY –
A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA (2.5 CM).
B. VISCERAL PLEURAL INVASION IDENTIFIED.
C. ANGIOLYMPHATIC INVASION IDENTIFIED.
D. ALL MARGINS OF RESECTION FREE OF TUMOR.
E. BACKGROUND LUNG SHOWING EMPHYSEMA, AIRSPACE SMOKER'S MACROPHAGES, AND
BRONCHIOLOECTASIS.
F. STAGE T2 N1 MX.

PART 7: LYMPH NODE, MIDDLE LOBE SUMP NODE, BIOPSY –
ONE OF ONE (1/1) LYMPH NODE WITH METASTATIC ADENOCARCINOMA.

PART 8: PLEURA, BIOPSY –
PORTION OF BENIGN FIBROADIPOSE TISSUE, PLEURA, AND SKELETAL MUSCLE.

Source: NCI Genomic Data Commons file 697ccc57-3e2e-453a-be58-e61c1376517d (TCGA-50-5045.1D5C2F0F-4203-4DB9-B63C-B6D80D04207E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).